Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L8, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L8-01A (Primary Tumor).

Procedure: adrenalectomy

Gross description: 7 x 5 x 4.5cm, 127g

Diagnosis: adrenocortical carcinoma, KI67 5%

Reference Pathology only:

Weiss score: 4

Hough score: 2.29

Van Slooten score: 9

ICD-O-3

Carcinoma, adrenal
Cortical 8370/3

Site: Adrenal Gland cortex

QID 2/6/13 @ 74.0

Criteria	W 1/14/13	Yes	No
Site of Origin discrepancy			
Diagnosis/Synchronicity Primary Noted			

Source: NCI Genomic Data Commons file 77a41a83-566f-4103-a2d7-c6c8c142c37b (TCGA-OR-A5L8.C4BBFD0B-83D0-47C8-9662-13691FE6D820.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).